Somatic mutation profile of tumor specimen 0DV7GW from CCDI case PBCEHT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.2 years (4,809 days).
Specimen 0DV7GW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e080af06-4645-4565-83eb-847f67b3f76d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV7GT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60230885-e583-459c-ab16-2b85adfef0b4

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/860 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- PAH | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 115/995 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs5030859, CM920562, COSV61014466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO1H | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 77/762 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 16/355 reads (5%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/60 reads (7%) | catalogued as COSV55814242; called by muse, mutect2
- PJVK | c.211+73C>G | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- TINAGL1 | c.467+35C>T | Intron (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
